CCDI case PBCGJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/8319d373-bc5a-49f7-8dfb-db0ae596f968

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.8 years (2,831 days).

Biospecimens (3 samples)
- Sample 0DSEYS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZ5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEZI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
